Gene-level copy-number profile of specimen HCM-CSHL-0512-C24-85N from HCMI case HCM-CSHL-0512-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,746 days).
Specimen HCM-CSHL-0512-C24-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce7f9ac8-845a-4126-a3f8-7a07d3d62c0e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0512-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/3f74331c-5983-4151-89f2-41741393cf6e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 11,316; copy number 2: 45,006; copy number 3: 1,605; copy number 4: 113; copy number 5: 96; copy number 6: 55; copy number 7: 35; copy number 8: 39; copy number 9: 39; copy number 10: 12; copy number 11: 21; copy number 12: 13; copy number 14: 6; copy number 15: 2; copy number 16: 8; copy number 17: 8; copy number 20: 20.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 354 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:69,180,234–71,302,864, 49 genes, copy number 7–9: SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622, UNC5B, UNC5B-AS1.
- chr10:73,625,996–73,730,487, 11 genes, copy number 5: AC073389.1, AC073389.3, MYOZ1, SYNPO2L, AC073389.2, AGAP5, BMS1P4-AGAP5, BMS1P4, AC022400.4, RNA5SP320, BMS1P4.
- chr10:78,943,328–79,316,528, 3 genes, copy number 5: ZMIZ1-AS1, AL356753.1, ZMIZ1.
- chr12:48,559,882–48,682,238, 8 genes, copy number 5–12: OR5BS1P, LALBA, OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B.
- chr12:51,351,247–51,812,864, 6 genes, copy number 6–7: GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1.
- chr12:52,674,736–52,680,407, 1 gene, copy number 7: KRT1.
- chr12:52,885,429–53,079,404, 9 genes, copy number 5–6: RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3.
- chr12:55,434,734–55,585,471, 2 genes, copy number 5 (within-gene range 2–5): AC122685.1, OR6C2.
- chr12:55,522,593–56,300,391, 62 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr12:56,981,211–56,985,960, 1 gene, copy number 6: AC026120.1.
- chr12:57,738,013–58,395,138, 28 genes, copy number 5–6 (within-gene range 4–6): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:64,222,337–64,397,065, 1 gene, copy number 6 (within-gene range 3–6): AC012158.1.
- chr12:64,264,762–69,699,476, 131 genes, copy number 5–20 (within-gene range 3–20) (broad region; genes not listed).
- chr12:70,638,073–72,670,758, 27 genes, copy number 6–10: PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:75,020,969–75,390,928, 8 genes, copy number 16–17: AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:80,707,634–80,937,925, 7 genes, copy number 9–12 (within-gene range 1–12): MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.

Autosomal genes at a single copy (total copy number 1): 11,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
